HCMI case HCM-CSHL-1267-C22 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/43e0c10d-9f88-4715-b476-9ce8f9f8f421

Demographics
Sex at birth: male; Year of birth: 1943; Vital status: Dead; Days to death: 123 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Cholangiocarcinoma: ICD-O-3 morphology code: 8160/3; ICD-10 code: C22.1; Tissue or organ of origin: Intrahepatic bile duct; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 77.3 years (28,216 days); AJCC staging edition: 8th; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: GX; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Perineural invasion present: Yes; Tumor largest dimension diameter: 8.5 cm; Vascular invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -53 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 123.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Liver Cirrhosis (Liver Disease).
- Timepoint category: Initial Diagnosis; Weight: 75 kg; Height: 170 cm; BMI: 26.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Liver Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-1267-C22-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-1267-C22-01A-01-S1-HE: Section location: Top; Percent tumor cells: 19; Percent tumor nuclei: 40; Percent normal cells: 28; Percent necrosis: 0; Percent stromal cells: 53; Percent lymphocyte infiltration: 11; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-1267-C22-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 23; Percent tumor nuclei: 46; Percent normal cells: 27; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 12; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-1267-C22-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
